Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7056, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7056-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Patient with history of left LE sarcoma and incidental right renal mass.

Specimens Submitted:

1: Kidney, right; core biopsy

2: Kidney, right; radical nephrectomy

3: Lymph nodes, pre and paracaval; excision

DIAGNOSIS:

1. Kidney, right; core biopsy:

Renal cortical neoplasm.

2. Kidney, right; radical nephrectomy:

Tumor Type:

High grade renal cell carcinoma with extensive papillary, cribriform, and solid features, most compatible with a tumor of distal nephron/collecting duct origin; see note

Tumor Size:

Greatest diameter is 3.6 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Tumor invades medium to large size muscular vessels as well as lymphatic spaces in the region of the renal sinus

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild interstitial chronic inflammation.

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

Note: The tumor exhibits multinodular growth, desmoplasia, and necrosis. Immunohistochemical stains are positive for CK7 (focal, strong), Racemase (diffuse, strong), and 34BE12 (focal, weak), while negative for CK20 and CA-9. Although this tumor does

[page 2 of 4]
[REDACTED]

exhibit an extensive papillary growth pattern, its range of features and immunoprofile are most compatible with a distal nephron/collecting duct tumor. This case was reviewed with the [REDACTED] Consensus Conference which concurs with the diagnosis.

3. Lymph nodes, pre and paracaval; excision:

Lymph Nodes:

Not involved

Number of nodes examined: 11

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	
	RECUT	
	RECUT	
	RECUT	
	CK7	
	RACEMASE	
	34BE12	
	CK20	
	CA-1X	
	NEG CONT	
	IMM RECUT	
	CD117	
	RECUT	
	RECUT	
	RECUT	
	RECUT	

Gross Description:

[REDACTED]

1). The specimen is received fresh for frozen section consultation, labeled "Right renal mass biopsy" and consists of a piece of soft tissue measuring 1.0 x 0.2 x 0.1 cm. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

[REDACTED]

2). The specimen is received fresh for frozen section consultation, labeled "right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 180 g in total. The kidney measures 11 x 7.5 x 3 cm. The attached ureter measures 2.7 cm in length and 0.4 cm in diameter. The attached renal vein measures 1 cm in length and 0.8 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a heterogeneous tan pink to golden yellow infiltrating tumor that is focally very friable that measures 3.6 x 3.4 x 2.5 cm located in the cortex with focal extension to the perirenal fat and also extension to the medulla and focally to the renal sinus fat. The tumor is not involving the renal pelvic or renal hilar fat. Sections through the remainder of the kidney reveal pink brown parenchyma with a well-defined cortico-medullary junction. The cortex measures 0.7 cm and the calyces appear normal. No

[page 3 of 4]
lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins
T -- tumor
HF -- tumor with hilar fat
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections
K -- representative sections kidney
TCF -- tumor to capsule and perirenal fat
FCS -- frozen control section

3). The specimen is received in formalin, labeled "Pre and para caval lymph nodes" and consists of six pink tan firm lymph nodes ranging from 0.4 to 2.7 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph node

Summary of Sections:

Part 1: Kidney, right; core biopsy

Block	Sect. Site	PCs
1	FSC	1

Part 2: Kidney, right; radical nephrectomy

Block	Sect. Site	PCs
1	FCS	1
1	HF	1
1	K	1
1	RP	1
2	T	2
2	TCF	2
2	TK	2
2	TSF	2
1	UVM	1

Part 3: Lymph nodes, pre and paracaval; excision

Block	Sect. Site	PCs
2	BLN	2
2	LN	5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: RIGHT RENAL MASS BIOPSY [REDACTED] EPITHELIAL NEOPLASM, DEFER. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
2. FROZEN SECTION DIAGNOSIS: SP: RIGHT KIDNEY [REDACTED] RENAL CORTICAL CARCINOMA, WITH PROMINENT PAPILLARY ARCHITECTURE. [REDACTED]
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file d65acc8b-23e7-4fca-ab70-44f74b41fdd5 (TCGA-BQ-7056.C4744171-FE46-4E36-A106-D5C4C09AE664.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).